Somatic mutation profile of tumor specimen TARGET-10-PAPFPZ-09A (aliquot TARGET-10-PAPFPZ-09A-01D) from TARGET case TARGET-10-PAPFPZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,364 days).
Specimen TARGET-10-PAPFPZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d3fc7c5-17cc-49c8-8ec1-0529f44b11ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFPZ-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFPZ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbc89f6e-1b15-49a9-822c-7e66d8aac594

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 2, Intron 2, In Frame Del 1, Splice Region 1, Nonstop Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8631G>C p.L2877F | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794840, COSV53731479, COSV53748161, COSV53750285; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFIT3 | c.920T>C p.I307T | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.665); catalogued as rs915392549; called by muse, mutect2
- JAKMIP3 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs747360916, COSV53819314; called by muse, mutect2, varscan2
- KIF18A | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs757886643; called by muse, mutect2, varscan2
- PLEKHS1 | c.184C>T p.R62* (on ENST00000369310 / NM_182601.1; = p.R68* on NM_024889.5) | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as rs758365422; called by muse, mutect2, varscan2
- PNLIPRP3 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs554228981; called by muse, varscan2
- SMARCA5 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as COSV51645714; called by muse, mutect2, varscan2
- ANXA10 | c.488G>C p.R163T | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- DAPK1 | c.-108G>C | Splice Region (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- DNAH8 | c.7439C>A p.S2480Y | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- GABRA2 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- IGHV3-33 | chr14:106359782 CTCACTGTGTCTCTCGCACAG>TGCGGA | Missense Mutation (DEL) | VAF 30/33 reads (91%) | called by pindel, varscan2*
- INSL6 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- KDM4B | c.2700_2701insGGTCCTGGG p.S900_I901insGPG | In Frame Ins (INS) | VAF 7/51 reads (14%) | called by mutect2, pindel
- LRRC71 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OR2F2 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PMP22 | c.482G>C p.*161Sext*10 | Nonstop Mutation (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- RBM45 | c.1159G>A p.E387K (on ENST00000616198 / NM_001365579.1; = p.E385K on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- REEP3 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WASF2 | c.355_366del p.P119_E122del | In Frame Del (DEL) | VAF 32/75 reads (43%) | called by mutect2, pindel*, varscan2*
- GLMN | c.1311C>T p.N437= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs753222419; called by muse, mutect2, varscan2
- LRRC37A3 | c.4800C>T p.C1600= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs753835090; called by muse, mutect2, varscan2
- MTERF2 | c.273G>A p.E91= | Silent (SNP) | VAF 70/142 reads (49%) | called by muse, mutect2, varscan2
- SPTBN5 | c.6690G>A p.L2230= | Silent (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- STAB2 | c.4326C>A p.T1442= | Silent (SNP) | VAF 53/89 reads (60%) | called by muse, mutect2, varscan2
- TEKT1 | c.429C>A p.I143= | Silent (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- KCNT1 | c.1345-31G>A | Intron (SNP) | VAF 7/16 reads (44%) | catalogued as rs752797445; called by muse, mutect2, varscan2
- SETBP1 | c.4000+16779C>A | Intron (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
